Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5988, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5988-01A (Primary Tumor).

[page 1 of 4]
PATHOLOGIC DIAGNOSIS:

A/1. SPECIMEN LABELED "RIGHT RADICAL NEPHRECTOMY":

CLEAR CELL RENAL CELL CARCINOMA, Fuhrman nuclear grade II, of IV (6.0 cm) arising in the right lower pole.

Tumor is limited to the kidney.

Ureteral, renal artery, renal vein, and Gerota's fascia margins are negative for tumor.

Lymphovascular invasion is present but no involvement of the main renal vein is seen.

AJCC Classification (6th Edition): T1b NX MX.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

B/2. SPECIMEN LABELED "REGIONAL LYMPH NODES":

Fibroadipose tissue with no significant pathologic change.

No lymph nodes identified.

There is no evidence of malignancy.

CLINICAL DATA:

History: None given.

Operation: Right radical nephrectomy, regional lymph node dissection.

Operative Findings: None given.

Clinical Diagnosis: Renal cell carcinoma.

TISSUE SUBMITTED:

A/1. Right radical nephrectomy to FS at [REDACTED]

B/2. Regional lymph nodes.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, "#1. Right radical nephrectomy", consists of a 510-gram radical nephrectomy specimen (23.0 x 11.0 x 6.5 cm), with an ureter (5.0 x 0.3 cm), a renal artery (0.7 x 0.3 cm), and a renal vein (0.2 x 1.3 cm). The attached Gerota fascia consists of tan/yellow lobulated adipose tissue. The capsule strips with ease over the majority of the specimen except focally above the inferior pole. A tan to tan/orange, partially hemorrhagic tumor (6.0 x 4.0 x 5.5 cm). There is also a unilocular cyst containing tan/yellow serous fluid (3.0 x 2.0 x 2.2 cm). The tumor extends to the outer surface of the kidney but does not involve the surrounding Gerota's fascia. The tumor is located in the lower pole, 5.5 cm from the ureteral margin, 3.0 cm from the renal vein, 1.5 cm from the renal artery, and 0.5 cm from the perinephric margin (inked black). The distal end of the renal artery (0.1 cm from the margin) is focally firm. The remaining renal cortex is tan/brown with a well-defined corticomedullary junction. The pelvis and calyces are covered by smooth, glistening mucosa. A representative section of tumor is submitted to cytogenetics, and the tissue bank. Representative section of the cortex and medulla are submitted to tissue bank, and for EM and IF.

Micro A1: Renal artery and vein margins, 2 frags, [REDACTED]

Micro A2: Additional section of renal artery, 1 frag, [REDACTED]

Micro A3: Ureteral margin, 1 frag, [REDACTED]

Micro A4: Quick fix (tissue adjacent to tissue taken for tissue banking), 1 frag, [REDACTED]

Micro A5: Quick fix (tissue taken adjacent to tissue taken for tumor banking)

[page 2 of 4]
1 frag, [REDACTED]
Micro A6-A7: Tumor to Gerota's fascia, with the section of cyst in A7, 2 frags total, [REDACTED]
Micro A8: Section of tumor to hilar fat, 1 frag, [REDACTED]
Micro A9: Section of tumor to normal, 1 frag, [REDACTED]
Micro A10: Normal kidney, 1 frag, [REDACTED]

Part B, "#2. Regional lymph node", consists of an irregular tan/yellow, lobulated portion of adipose tissue (2.4 x 2.0 x 1.0 cm) with no definitive lymph node structures.

Micro B1: 1 frag, [REDACTED]
[REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

ADDENDUM #1

RENAL PATHOLOGY EVALUATION OF NON-NEOPLASTIC KIDNEY PARENCHYMA

RIGHT KIDNEY, NEPHRECTOMY:

KIDNEY WITH MINOR, NON-SPECIFIC ABNORMALITIES (SEE NOTE)

NOTE:

The sample of kidney parenchyma shows minimal chronic changes. The changes are non-specific and do not point to a specific disease entity. There is very mild glomerular hypertrophy, but the glomeruli are well preserved. Minimal tubular atrophy and interstitial fibrosis (less than 5% of the parenchyma) is noted, and arteries and arterioles also show minimal chronic damage.

[REDACTED]
Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A10) were evaluated by light microscopy using H&E, PAS, [REDACTED] silver methenamine, and AFOG (trichrome) stains.

The sample consists of kidney cortex and medulla. There are 206 glomeruli present, of which one (1) is globally sclerosed. The glomeruli show mild glomerular hypertrophy and minimal focal expansion of the mesangial areas. There are only isolated, mild irregularities of the glomerular capillary wall basement membranes. Rare distal tubules contain PAS-positive hyaline casts. Isolated tubular epithelial cells contain small quantities of protein reabsorption granules. Less than 5% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit mild, focal sclerosis of the wall.

[page 3 of 4]
KARYOTYPE: 45,XY,der(3)t(3;8)(p21;q22),-8[4]/92,XXYY[1]

METAPHASES COUNTED: 5 ANALYZED: 5 SCORED: 5 BANDING: GTG

INTERPRETATION:

4 of 5 metaphase cells contained an unbalanced translocation, resulting in deletion of the chromosome 3 short arm. This cytogenetic aberration is a typical finding in renal cell carcinoma, clear cell type.

COMMENTS:

Mosaicism and small chromosome abnormalities may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

[REDACTED]

[REDACTED]

[page 4 of 4]
~~CONFIDENTIAL~~

~~CONFIDENTIAL~~

Source: NCI Genomic Data Commons file f38fdca5-ab52-47be-83d5-9c68b7189934 (TCGA-CZ-5988.5D8DE52F-5187-47FF-A550-F9F1AE2A8DE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).